MMRF case MMRF_2194 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b8059fa5-8fa3-4a5f-aa8d-3bdf66cbb05f

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 75 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 75.5 years (27,574 days); ISS stage: II; Days to last known disease status: 901 days (2.5 years); Days to last follow up: 901 days (2.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 289 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 449 days (1.2 years); Days to treatment end: 591 days (1.6 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 542 days (1.5 years); Days to treatment end: 591 days (1.6 years).
   Treatment given: Therapeutic agents: Dexamethasone + Other + Vincristine; Regimen or line of therapy: Third line of therapy; Days to treatment start: 592 days (1.6 years); Days to treatment end: 648 days (1.8 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 670 days (1.8 years); Days to treatment end: 787 days (2.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.161 mg/dL; Immunoglobulin G 4.66 g/L; Immunoglobulin A 0.407 g/L; Immunoglobulin M 0.173 g/L; Beta 2 Microglobulin 4.57 µg/mL; Lactate Dehydrogenase 3.58 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 94 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 7.64 mmol/L; Calcium 2.52 mmol/L; Albumin 27.5 g/L; Total Protein 6.2 g/dL; Glucose 5.01 mmol/L.
- Day 95 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 9.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.484 mg/dL; Immunoglobulin G 3.98 g/L; Immunoglobulin A 0.297 g/L; Immunoglobulin M 0.178 g/L; Beta 2 Microglobulin 4.74 µg/mL; Hemoglobin 6.39 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 57 ×10⁹/L; Creatinine 69 µmol/L; Calcium 2.37 mmol/L; Albumin 35.9 g/L; Total Protein 6.21 g/dL; Glucose 5.61 mmol/L.
- Day 184 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 1.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.682 mg/dL; Immunoglobulin G 5.48 g/L; Immunoglobulin A 0.378 g/L; Immunoglobulin M 0.168 g/L; Hemoglobin 6.63 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 62.8 µmol/L; Calcium 2.19 mmol/L; Albumin 32.6 g/L; Total Protein 6.04 g/dL; Glucose 5.34 mmol/L.
- Day 275 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.16 mg/dL; Immunoglobulin G 6.3 g/L; Immunoglobulin A 0.603 g/L; Immunoglobulin M 0.168 g/L; Beta 2 Microglobulin 2.65 µg/mL; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 6.17 mmol/L; Calcium 2.38 mmol/L; Albumin 36.4 g/L; Total Protein 6.52 g/dL; Glucose 5.34 mmol/L.
- Day 341 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 7.63 g/L; Immunoglobulin A 0.952 g/L; Immunoglobulin M 0.168 g/L; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.48 mmol/L; Albumin 36.4 g/L.
- Day 443: Serum Free Immunoglobulin Light Chain, Kappa 3.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.341 mg/dL; Immunoglobulin G 6.09 g/L; Immunoglobulin A 0.507 g/L; Immunoglobulin M 0.0745 g/L; Hemoglobin 5.27 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 80 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 10.5 mmol/L; Calcium 2.04 mmol/L; Albumin 22.6 g/L; Total Protein 5.48 g/dL; Glucose 6.44 mmol/L.
- Day 544 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 3.66 g/L; Immunoglobulin A 0.422 g/L; Immunoglobulin M 0.168 g/L; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 36 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 4.67 mmol/L; Calcium 2.07 mmol/L; Albumin 27.2 g/L; Glucose 7.26 mmol/L.
- Day 628 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 2.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.26 mg/dL; Immunoglobulin G 2.72 g/L; Immunoglobulin A 0.143 g/L; Immunoglobulin M 0.0417 g/L; Beta 2 Microglobulin 5.88 µg/mL; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 5.21 mmol/L; Leukocytes 1.5 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 21 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 3.5 mmol/L; Calcium 2.24 mmol/L; Albumin 25.3 g/L; Glucose 4.57 mmol/L.
- Day 731 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.3 mg/dL; Immunoglobulin G 2.45 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.0417 g/L; Beta 2 Microglobulin 5.55 µg/mL; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 24 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 4.17 mmol/L; Calcium 1.7 mmol/L; Albumin 23 g/L; Total Protein 5.04 g/dL; Glucose 5.06 mmol/L.
- Day 803 (ECOG 2): M Protein 0 g/dL; Immunoglobulin G 2.12 g/L; Immunoglobulin A 0.299 g/L; Immunoglobulin M 0.0417 g/L; Beta 2 Microglobulin 6.41 µg/mL; Lactate Dehydrogenase 10.9 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 31 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 5.17 mmol/L; Calcium 2.21 mmol/L; Albumin 25.7 g/L; Total Protein 5.18 g/dL; Glucose 5.56 mmol/L.
- Day 901 (ECOG 2): Immunoglobulin G 2.38 g/L; Immunoglobulin A 0.0694 g/L; Immunoglobulin M 0.0417 g/L; Beta 2 Microglobulin 4.74 µg/mL; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 5.33 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 32 ×10⁹/L; Creatinine 48.6 µmol/L; Blood Urea Nitrogen 2.67 mmol/L; Calcium 2.12 mmol/L; Albumin 27.5 g/L; Total Protein 4.8 g/dL; Glucose 5.67 mmol/L.

Other clinical attributes
- Day 1: Weight: 80 kg; Height: 163 cm.

Biospecimens (3 samples)
- Sample MMRF_2194_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2194_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
- Sample MMRF_2194_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 443 days (1.2 years).
